Somatic mutation profile of tumor specimen 0DS1JR from CCDI case PBCHDK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,794 days).
Specimen 0DS1JR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e95c1f19-8bd9-40a5-9aaa-7af8acfd930a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS1JP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d53b6439-c7d8-4cfa-adbb-9cba43df2f05

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Nonsense Mutation 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KITLG | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 416/2243 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs375568814, COSV57203828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC55 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 60/348 reads (17%) | catalogued as rs772493808, COSV101546741, COSV73006803; called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 46/1296 reads (4%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
